Somatic mutation profile of tumor specimen TCGA-LK-A4O6-01A (aliquot TCGA-LK-A4O6-01A-11D-A34C-32) from TCGA case TCGA-LK-A4O6, project TCGA-MESO (Mesothelioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mesothelioma, biphasic, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 66.9 years (24,449 days).
Specimen TCGA-LK-A4O6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 674c927a-d69a-4e58-982d-051596a33d4d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LK-A4O6-10A (Blood Derived Normal), aliquot TCGA-LK-A4O6-10A-01D-A34C-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8af1394d-4e91-4c21-a2df-4f894526fa27

The open-access MAF lists 26 somatic variants for this specimen: 23 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 16, Frame Shift Del 3, Silent 3, Nonsense Mutation 2, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FARP1 | c.2444G>T p.S815I | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as COSV60333197; called by muse, mutect2, varscan2
- LRFN5 | c.1082A>G p.N361S | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767527817; called by muse, mutect2, varscan2
- LRP2 | c.12727C>T p.R4243* | Nonsense Mutation (SNP) | VAF 12/94 reads (13%) | catalogued as COSV55547813; called by muse, mutect2, varscan2
- MCF2 | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.072); catalogued as rs865955898, COSV58490679; called by mutect2, varscan2
- NRK | c.4547G>A p.G1516D | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as rs186516629; called by muse, mutect2, varscan2
- NUP88 | c.517C>G p.L173V | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs774993752; called by muse, mutect2, varscan2
- TAS1R2 | c.2366C>T p.T789I | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.906); catalogued as COSV64746831; called by muse, mutect2, varscan2
- TNC | c.2797G>A p.G933R | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1259197648, COSV60790910; called by muse, varscan2
- ACP7 | c.118C>A p.P40T | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- BAP1 | c.28_37+8del p.X10_splice | Splice Site (DEL) | VAF 7/40 reads (18%) | called by mutect2, pindel
- BEND7 | c.1000G>T p.A334S | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- CARS2 | c.1417-1G>A p.X473_splice | Splice Site (SNP) | VAF 14/100 reads (14%) | called by muse, mutect2, varscan2
- CLNK | c.506T>A p.L169H | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2
- H3C7 | c.376C>A p.Q126K | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- LMTK3 | c.2434del p.A812Rfs*46 | Frame Shift Del (DEL) | VAF 8/49 reads (16%) | called by mutect2, pindel, varscan2
- NAP1L1 | c.622C>T p.Q208* | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2, varscan2
- NMT1 | c.841_857del p.Y281Tfs*22 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | called by mutect2, pindel*
- PCDHGA11 | c.1123C>G p.Q375E | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.035); called by muse, mutect2
- POGLUT1 | c.186del p.E63Rfs*3 | Frame Shift Del (DEL) | VAF 9/50 reads (18%) | called by mutect2, pindel
- PRDM14 | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SAMD9L | c.1369A>C p.K457Q | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- SV2C | c.2026G>A p.A676T | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- UGT2B4 | c.1123G>C p.G375R | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ENPP3 | c.2382G>A p.P794= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as rs771979545; called by muse, mutect2, varscan2
- INO80 | c.4071C>T p.F1357= | Silent (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2, varscan2
- RTL4 | c.177G>A p.E59= | Silent (SNP) | VAF 12/88 reads (14%) | called by muse, mutect2, varscan2
